Somatic mutation profile of tumor specimen TCGA-WC-AA9E-01A (aliquot TCGA-WC-AA9E-01A-11D-A39W-08) from TCGA case TCGA-WC-AA9E, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.2 years (21,976 days).
Specimen TCGA-WC-AA9E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26fd61ac-74ae-4071-a9d6-49d6950ea8c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-AA9E-10A (Blood Derived Normal), aliquot TCGA-WC-AA9E-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cf48698-7e33-4ce4-9f4e-d0911933d369

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.1357G>A p.V453M (on ENST00000506720 / NM_001322402.2; = p.V385M on NM_015236.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298975938, COSV72265533; called by muse, mutect2, varscan2
- CSMD3 | c.3911C>G p.T1304S (on ENST00000297405 / NM_001363185.1; = p.T1200S on NM_052900.3) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.043); catalogued as rs143652338, COSV52217443; called by muse, mutect2, varscan2
- MCRS1 | c.199del p.A67Qfs*53 | Frame Shift Del (DEL) | VAF 57/170 reads (34%) | catalogued as COSV59459776; called by mutect2, pindel, varscan2
- MGAT4B | c.1041+1G>A p.X347_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as rs112845536; called by muse, mutect2, varscan2
- OCLN | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762992411, COSV62285701; called by muse, mutect2, varscan2
- RSPH14 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as COSV53267094; called by muse, mutect2, varscan2
- SELE | c.949T>A p.C317S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs936834236; called by muse, mutect2, varscan2
- ABCA12 | c.3106C>G p.Q1036E (on ENST00000272895 / NM_173076.3; = p.Q718E on NM_015657.3) | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CACNA1D | c.3826A>T p.I1276F (on ENST00000350061 / NM_001128840.3; = p.I1296F on NM_000720.4) | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SAP30BP | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2
- ARHGEF17 | c.4800G>A p.A1600= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs748441561; called by muse, mutect2
- GAB3 | c.1533G>A p.E511= | Silent (SNP) | VAF 64/68 reads (94%) | catalogued as COSV100850443; called by muse, mutect2, varscan2
- WDR7 | c.3762T>A p.S1254= | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- ZNF304 | c.876C>T p.H292= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
